Somatic mutation profile of tumor specimen MP2PRT-PAVTIT-TMP1-A (aliquot MP2PRT-PAVTIT-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVTIT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,476 days).
Specimen MP2PRT-PAVTIT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6da802af-62fa-4b7a-a633-585c835ab37e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTIT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTIT-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eebbfb33-7d45-428a-bc2c-5f7815357b54

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 205/545 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1365198389; called by muse, mutect2, varscan2
- AMY2A | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 50/640 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs777496434, COSV70214489; called by muse, mutect2
- CHSY3 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 217/801 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1379237412; called by muse, mutect2, varscan2
- CRACD | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs775295493; called by muse, varscan2
- CRYGC | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 82/299 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56409709; called by muse, mutect2, varscan2
- DNAH6 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV52855339; called by muse, mutect2, varscan2
- PDZD3 | c.488C>T p.A163V (on ENST00000531114; = p.A97V on NM_024791.4) | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.395); catalogued as rs771058357, COSV52704009; called by muse, varscan2
- SGSM1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 60/572 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1460177094; called by muse, mutect2
- TENT4A | c.2017C>G p.Q673E | Missense Mutation (SNP) | VAF 81/326 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50102134; called by muse, mutect2, varscan2
- TEX44 | c.135C>G p.D45E | Missense Mutation (SNP) | VAF 129/423 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1399352728; called by muse, mutect2, varscan2
- ZIC1 | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 224/859 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs750620561; called by muse, mutect2, varscan2
- BCCIP | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 8/245 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0.029); called by muse, mutect2
- DOT1L | c.2353C>A p.L785M | Missense Mutation (SNP) | VAF 130/482 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GLIPR1L1 | c.398G>C p.R133T | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2
- JAM3 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 136/546 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- LRGUK | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 14/418 reads (3%) | called by muse, mutect2
- LRRN3 | c.1362C>G p.I454M | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- NBPF12 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 94/568 reads (17%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR13C9 | c.875A>T p.N292I | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8B12 | c.783_784insT p.L262Sfs*29 | Frame Shift Ins (INS) | VAF 91/354 reads (26%) | called by mutect2, pindel, varscan2
- OTOGL | c.2513C>G p.S838C (on ENST00000547103; = p.S829C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PPFIA2 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- RAB23 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 55/314 reads (18%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 75/495 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TGFBR2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 115/459 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- TTN | c.97168G>A p.E32390K (on ENST00000591111; = p.E24966K on NM_003319.4) | Missense Mutation (SNP) | VAF 40/197 reads (20%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- VARS1 | c.1460A>C p.D487A | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- VPS13B | c.3868G>A p.E1290K | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF462 | c.1085G>C p.R362T | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARPC2 | c.888G>A p.T296= | Silent (SNP) | VAF 95/529 reads (18%) | catalogued as rs745663634; called by muse, mutect2, varscan2
- CRISPLD1 | c.798C>T p.V266= | Silent (SNP) | VAF 66/291 reads (23%) | called by muse, mutect2, varscan2
- FAT2 | c.1326C>T p.T442= | Silent (SNP) | VAF 30/517 reads (6%) | catalogued as rs772411485; called by muse, mutect2
- LMOD1 | c.945C>T p.P315= | Silent (SNP) | VAF 17/582 reads (3%) | called by muse, mutect2
- LOX | c.504C>T p.G168= | Silent (SNP) | VAF 44/638 reads (7%) | called by muse, mutect2
- PTCD2 | c.867G>A p.L289= | Silent (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2
- SMPDL3A | c.522C>T p.L174= | Silent (SNP) | VAF 35/337 reads (10%) | catalogued as COSV63755819; called by muse, mutect2, varscan2
- SYN3 | c.339G>A p.V113= | Silent (SNP) | VAF 50/231 reads (22%) | catalogued as rs770613209; called by muse, mutect2, varscan2
- TEX13D | c.36C>T p.F12= | Silent (SNP) | VAF 26/401 reads (6%) | called by muse, mutect2
- APOL1 | c.*537G>C | 3'UTR (SNP) | VAF 14/502 reads (3%) | called by muse, mutect2
- KCNQ1 | c.1394-9236C>T | Intron (SNP) | VAF 77/293 reads (26%) | catalogued as rs1394618769; called by muse, mutect2, varscan2
- OSGIN1 | n.1661G>A | RNA (SNP) | VAF 173/618 reads (28%) | called by muse, mutect2, varscan2
